Surgical pathology report (de-identified scan), TCGA case TCGA-12-3646, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-3646-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

TCGA-12-3646

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Brain tumor. MRI: A mass is identified in the right temporoparietal region measuring 5.7 x 5.7 x 5.2 cm CC x TV x AP. The majority of the mass has a thin rim of peripheral enhancement. However, there are more irregular, thickened enhancing areas inferolaterally. It is centered lateral to the ventricle causing mass-effect upon it.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh. A 4.8 x 3.5 x 2 cm aggregate of soft red-tan tissue is received. Representative is frozen as AF1 and the remnant is submitted as A1. Additional sections are submitted as A2-3. Tissue is retained in formalin as well.

B. "Brain tissue", received fresh. A 2.0 x 1.4 x 0.4 cm fragment of pink-tan brain tissue is received. The majority is submitted as B1, a small amount is retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- glioblastoma. [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by marked cytologic pleomorphism with multinucleated tumor cells, mitotic figures, glomeruloid microvascular proliferation and pseudopalisading necrosis.

DIAGNOSIS:

A. "BRAIN TUMOR" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

B. "BRAIN TUMOR" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (67% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - POLYSOMY (66% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (44% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (39% OF TUMOR CELLS EXHIBIT LOSS)

[page 2 of 2]
4 OF 4 ABNORMAL MARKERS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 2:
IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED]).

MGMT - 5% OF TUMOR CELLS

EGFR wt - 3+ IN 80% OF TUMOR CELLS

EGFR vIII - NEGATIVE

PTEN - 2+ IN 5% OF TUMOR CELLS

pS6 - 3+ IN 20% OF TUMOR CELLS

pAKT - 3+ IN 60% OF TUMOR CELLS

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED]

Source: NCI Genomic Data Commons file 145048ef-857c-4b33-902f-45fc78ad3a25 (TCGA-12-3646.47FAA88A-2D5F-4B53-AD5C-80123FE54844.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).